Surgical pathology report (de-identified scan), TCGA case TCGA-23-1124, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1124-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

PATIENT: [REDACTED]

Hospital No.: [REDACTED]

Date of Birth: [REDACTED]

Soc. Sec. No.: [REDACTED]

Location: [REDACTED]

Pathologist: [REDACTED]

Assistant: [REDACTED]

Attending MD: [REDACTED]

Ordering MD: [REDACTED]

Copies To: [REDACTED]

=====

DIAGNOSIS:

1. RIGHT FALLOPIAN TUBE AND OVARY, SALPINGO-OOPHORECTOMY:
- Ovary with:
- Subtotal replacement by cystadenocarcinoma, predominantly papillary serous type with minor component of tumor cells showing clear cell features, grade III (see comment)
- Serosal surface of ovary is involved by tumor
- Tumor-associated psammoma bodies are present
- Focal tumor-associated necrosis
- Serosal cystadenoma adjacent to malignant tumor
- Mesothelial cysts
- Fallopian tube with:
- Serosal surface involvement and invasion by secondary papillary serous carcinoma of ovarian origin
- Paratubal cystic Walthard rest
- Serosal adhesions, including tubo-ovarian adhesions
- Secondary reactive mesothelial hyperplasia
- Lymphovascular invasion by carcinoma is present in right adnexa (ovary and paratubal and paraovarian ligaments)
2. OMENTUM, PARTIAL OMENTECTOMY:
- Metastatic mullerian-derived carcinoma, predominantly papillary serous type and focal clear cell type
- Lymphovascular invasion by tumor is present
- Secondary acute and chronic inflammation with reactive lymphoid aggregates
- Adhesions
- Reactive mesothelial proliferation
3. LARGE INTESTINE, BIOPSY:
- Nodular aggregate of metastatic serous carcinoma
- Secondary inflammatory changes including accumulation of lipid-laden macrophages
- No bowel wall tissue or mucosa identified
4. SOFT TISSUE, CUL DE SAC, EXCISION:

[page 2 of 6]
- Tumor-associated necrosis is present focally
- Secondary acute and chronic inflammatory changes

5. UTERUS, LEFT FALLOPIAN TUBE AND OVARY, AND RIGHT ADNEXAL REMNANTS, TOTAL ABDOMINAL HYSTERECTOMY, LEFT SALPINGO-OOPHORECTOMY, AND EXCISION OF RIGHT ADNEXAL REMNANTS:

- High grade (grade III) mullerian-derived adenocarcinoma, predominantly papillary serous type and minor component of tumor with clear cell features noted in some involved sites involving:
- Left ovary with extensive (subtotal replacement) of parenchyma and serosal surface involvement by tumor
- Serosal surface of left fallopian tube
- Left mesosalpinx
- Lymphovascular invasion by tumor is present in left ovary, left fallopian tube and left adnexal soft tissues
- Right adnexal remnants/ligaments and right parametria, including lymphovascular invasion by tumor
- Serosal surface, virtual total wall thickness of uterus in some areas, and endometrium in some areas; both primary serous tumor (UPSC, nuclear grade 3) and secondary involvement of uterus by tumor extension from the adjacent adnexa appear to be present
- Lymphovascular invasion by tumor is present in the uterus and parametrial soft tissues
- Free floating aggregates of tumor are present in endometrial cavity in lower uterine segment
- Tumor-associated necrosis is present focally
- Inflammatory reaction to tumor is present focally
- Other findings include:
- Uterine leiomyoma with focal involvement by serous carcinoma
- Adenomyosis
- Endocervical nabothian cysts
- Mild acute and chronic cervicitis
- Atrophic and hyperplastic changes of squamous epithelium of cervix, including within endocervical glands showing squamous metaplasia

6. COLON, SIGMOID, "TUMOR", EXCISION:

- No specimen identified within the specimen container (see gross description)

7. SOFT TISSUE, LEFT GUTTER, EXCISION:

- Metastatic mullerian-derived carcinoma, predominantly serous type and minor component of tumor cells exhibiting clear cell features

8. LYMPH NODES, RIGHT PELVIC, EXCISION:

- Seven lymph node profiles showing reactive lymphoid changes, sinus histiocytosis, foci of fibrosis and/or calcifications; no evidence of metastatic carcinoma in lymph node or perinodal adipose tissue (0/7)
- Stray fragments of tumor separate from lymph nodes and peri-perinodal adipose tissue, apparently representing contaminants

9. LYMPH NODE, LEFT PELVIC, EXCISION:

- One reactive lymph node showing sinus histiocytosis, focal fibrosis, and calcifications
- No evidence of metastatic carcinoma within lymph nodes or perinodal adipose tissue (0/1)

10. SOFT TISSUE, DIAPHRAGM, "TUMOR", EXCISION:

- Metastatic mullerian-derived carcinoma, predominantly serous type and minor component of tumor exhibiting clear cell features

[page 3 of 6]
COMMENT: The mullerian-derived tumor exhibits predominantly serous features with solid growth predominating and papillary and glandular growth noted focally. Some of the tumor cells appear anaplastic/ "undifferentiated". There is a minor component of clear cell carcinoma seen in some, but not all, of the involved sites. Lymphovascular space invasion by tumor is present in many of the involved sites. As stated above, it appears that the uterus contains primary UPSC and also exhibits secondary invasion by extension of adnexal tumor. In light of [REDACTED] the [REDACTED] during the week beginning [REDACTED], the pathologic findings were instead discussed with [REDACTED]. Findings in additional sections have been incorporated in the diagnoses.

=====

HISTORY: Right ovarian tumor

MICROSCOPIC:
See Diagnosis.

GROSS:

1: RIGHT OVARY

Labeled "right ovary", received fresh in the Operating Room and subsequently fixed in formalin, is a 17 x 14 x 11 cm solid and cystic ovarian neoplasm. The cystic portion contains approximately 1000 cc of dark gray-red bloody fluid. There is an additional 10 x 5 x 4 cm cystic locule containing approximately 600 cc of clear straw-colored fluid. This neoplasm is approximately 30% solid and 70% cystic in composition. A portion of the solid area is submitted for clonogenic assay. The external surface of the ovary wrinkled, tan and white with multiple diffuse foci of tumor studding. The cystic area's inner cyst lining is smooth and tan-white to bosselated with abundant vasculature and no papillary excrescences. The wall thickness measures up to 0.1 cm. Upon sectioning, the "solid" areas of tumor, they appear to be composed of both firm solid tan-white tumor and softer, friable papillary tan tumor. No residual uninvolved ovarian parenchyma is identified. Adherent to the cystic portion of the ovary, there is a 11.2 cm long, fimbriated fallopian tube with a diameter ranging from about 0.5 to 0.8 cm. The serosal aspect of the tube shows a 1.5 cm tan tumor papillary and solid tumor nodule at its fimbriated end. The rest of the serosal surface of the fallopian tube is red-tan and relatively smooth. On section, there is a pinpoint patent lumen. Representative sections are submitted.

- A-C. Solid areas of ovarian tumor - 1 each
- D,E. Cystic areas of ovarian tumor - 3 each
- F. Serosal surface of ovary with tumor - 3
- G. Fallopian tube with and without tumor - 3

2: OMENTUM

Labeled "omentum", received fresh in the Operating Room and subsequently fixed in formalin, is a 22 x 6 x 3 cm portion of yellow lobulated omentum with abundant firm to soft, friable tan-white tumor nodules up to about 3 cm in diameter. Representative sections are submitted.

H. 2

3: LARGE BOWEL

Labeled "large bowel" and received in formalin is a 1.0 x 1.0 x 0.4 cm fragment of firm solid tan, focally hemorrhagic tumor.

I. All embedded - 2

[page 4 of 6]
4: CUL DE SAC

Labeled "cul de sac" and received in formalin is a 7.5 x 6.5 x 1.5 cm aggregate of tan firm to soft, friable tumor fragments and blood clot.

J. Representative sections - 2

5: UTERUS, CERVIX, LEFT OVARY

Labeled "uterus, cervix, left ovary" and received in formalin is a 150 gram total hysterectomy of uterus with attached left adnexa. The uterus measures 6.5 cm from cornu to cornu, 5.3 cm anterior to posterior, and 7.5 cm fundus to ectocervix. Multiple implants of tan granular tumor are adherent to the uterine serosa, primarily in the upper anterior and posterior corpus and fundus. There is also a 4.2 x 3.5 x 3.0 cm aggregate of tumor involving the right periadnexal/parametrial tissue. The cervix measures 2.5 cm in length and 2.0 cm in diameter. The ectocervix has a surface area of 2.2 x 2.0 cm and surrounds a slit-shaped 0.2 cm in diameter patent os. The ectocervix is lined by a smooth pale tan mucosa. The endocervical canal is 2.0 cm in length with a maximum width of 0.3 cm. The endocervix is lined by tan rugose mucosa and contains multiple nabothian cysts. The uterine cavity is 4.2 cm in length with a maximum width of 1.0 cm. The uterine cavity is distorted by the presence of a submucosal leiomyoma measuring 4.5 x 3.2 x 3.0 cm. The leiomyoma is well-circumscribed and has a firm whorled bulging cut surface with no areas of hemorrhage, necrosis or cystic degeneration present. The endometrium is tan-red and ranges from less than 0.1 to about 0.3 cm in thickness. The endometrium is focally papillated and friable consistent with involvement by tumor. In some areas, the endometrium is not recognizable, perhaps due to replacement of the uterus by invasive tumor from the adnexa. The myometrium is attenuated the area involved by the submucosal leiomyoma and focally in areas involved by invasive tumor. The right uterine wall is soft and necrotic and appears to be involved by tumor invading in from the right periadnexal/parametrial tissue. The left ovary measures 4.5 x 3.2 x 2.5 cm and has a smooth tan-yellow external surface with small adherent areas of tumor measuring up to 2.2 x 1.5 x 0.3 cm. The cut surface of the ovary is pale tan-yellow. The fallopian tube measures 5.5 cm in length and 0.5 cm in diameter and is adherent to the ovary and uterus by dense aggregates of tumor measuring 3.5 x 3.0 x 2.0 cm involving the mesosalpinx. The surrounding tumor does not appear to invade the fallopian tube grossly. The fallopian tube has a patent 0.1 cm lumen which appears free of tumor. Representative sections are submitted.

K. Anterior cervix - 1

L. Posterior cervix - 1

M. Anterior lower uterine segment - 1

N. Posterior lower uterine segment - 1

O. Anterior uterine corpus - 1

P. Posterior uterine corpus - 1

Q,R. Leiomyoma - 2 each

S-U. Ovary - 1 each

V. Distal fallopian tube - 3

W. Proximal fallopian tube - 3

X. Tumor in area of mesosalpinx - 1

Y. Tumor in area of right periadnexal/parametrial region - 2

Additional representative sections ():

DD. Anterior uterine corpus - 2

EE. Anterior uterine corpus - 2

FF. Posterior uterine corpus - 1

GG. Posterior uterine corpus - 1

HH. Posterior uterine corpus - 1

II. Posterior uterine corpus - 1

[page 5 of 6]
6: SIGMOID TUMOR

Labeled "sigmoid tumor" and received in formalin is a bottle of formalin. No specimen is identified within the container.

7: LEFT GUTTER

Labeled "left gutter" and received in formalin is a 6.5 x 6.0 x 2.0 cm aggregate of nodular fragments of semifirm tan tumor.

Z. Representative section - 1

8: RIGHT PELVIC LYMPH NODE

Labeled "right pelvic lymph node" and received in formalin is a 3 x 2 x 0.6 cm aggregate of yellow fatty tissue and seven soft tan lymph nodes ranging from about 0.1 to 1.6 cm in greatest dimension. No metastatic tumor is grossly evident. The entire specimen is embedded.

AA. Seven lymph nodes and perinodal fat - Multiple

9: LEFT PELVIC LYMPH NODE

Labeled "left pelvic lymph node" and received in formalin is a soft tan lymph node measuring 1.5 x 0.8 x 0.4 cm with scant attached perinodal fat. Upon bisecting the lymph node, no grossly evident metastatic tumor is seen.

BB. One bisected lymph node - 2

10: DIAPHRAGM TUMOR

Labeled "diaphragm tumor" and received in formalin is a 4.2 x 3.5 x 0.8 cm aggregate of fragments of semisoft to soft friable tan tumor.

CC. Representative sections - 2

OPERATIVE CONSULT (GROSS)

Right ovary:

- Grossly consistent with ovarian cystadenocarcinoma
- Representative portion of tumor submitted for clonogenic assay

Special Studies: Additional H&E-stained sections

[page 6 of 6]
[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 40ed58bc-d9e3-43bb-84db-62d830f5a19b (TCGA-23-1124.71415169-CB24-4D07-B9C7-A71CE0424D0D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).